Somatic mutation profile of tumor specimen 0DIZWD from CCDI case PBBVSH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 0.8 years (305 days).
Specimen 0DIZWD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20debea9-8649-4f82-b14f-d20cea63106a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIZVU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb8f09ab-ffa4-4a2a-9b75-5f00ee530349

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RSU1 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 57/810 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs746985155, COSV61709832; called by muse, mutect2
- PTGFRN | c.591C>T p.L197= | Silent (SNP) | VAF 67/581 reads (12%) | catalogued as rs751382518; called by muse, mutect2, varscan2
